Surgical pathology report (de-identified scan), TCGA case TCGA-KB-A6F7, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University Health Network, Toronto, specimen TCGA-KB-A6F7-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering MD:

Copy To:

Specimen(s) Received

1. Stom-Resection: total stomach & spleen/
2. Surgical Waste
3. Gallbladder
4. Stomach Resection: Proximal stomach
5. Stomach Resection: Distal & proximal rings

*ICD-O-3
Adenocarcinoma, intestinal type
Site: Body of stomach
8/14/13
C16.2
AD 6/28/13*

Diagnosis

1. Total gastrectomy and splenectomy specimen: poorly differentiated adenocarcinoma with focal neuroendocrine and neural differentiation, intestinal type, invading into submucosa, 1 of 30 lymph nodes positive for metastatic adenocarcinoma (1/30), all resection margins clear, underlying moderate chronic gastritis, intestinal metaplasia; spleen within normal limits. See synoptic report and microscopic description.

*per TSS, Neuroendocrine differentiation = 3-5% of cells.
BLR*

2. Surgical waste: fibroadipose tissue within normal limits, negative for dysplasia.
3. Gallbladder resection specimen: gallbladder within normal limits.
4. Proximal resection margin: negative for malignancy.
5. Distal and proximal rings: negative for malignancy.

Synoptic Data

----- MACROSCOPIC -----
Specimen Type: Total gastrectomy
Tumor Site: Body - Posterior wall
Body - Lesser curvature
Tumor Configuration: Exophytic (polypoid)
Tumor Size: Greatest dimension: 5.5 cm
Additional dimensions: 2.7 x 1.7 cm

----- MICROSCOPIC -----
Histologic Type: Adenocarcinoma, intestinal type
Histologic Grade: G3: Poorly differentiated
Pathologic Staging (pTNM): pT1b: Tumor invades submucosa
pN1: Metastasis in 1 to 6 perigastric lymph nodes
Number of lymph nodes examined: 30

[page 2 of 4]
Surgical Pathology Consultation Report

Margins:	Number of lymph nodes involved: 1 pMX: Distant metastasis cannot be assessed Proximal Margin uninvolved by invasive carcinoma Distal Margin uninvolved by invasive carcinoma Omental (Radial) Margins uninvolved by invasive carcinoma
Lymphatic (Small Vessel) Invasion (L):	Absent
Venous (Large Vessel) Invasion (V):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	Gastritis (type): moderate chronic

Electronically verified by:

Clinical History

Ca Liver

Gross Description

1. The specimen container is labeled with the patient's name and as "Stomach-resection: Total stomach and spleen".

RESECTION SPECIMEN: e.g. en bloc resection of total gastrectomy with attached splenectomy.

FIXATION: Received fresh, placed in formalin

DIMENSIONS:

Length along lesser curvature 16.0 cm
Length along greater curvature 29.0 cm
Circumference of distal gastric margin 12.0 cm
Circumference of proximal gastric margin 5.5 cm
Length of tubular esophagus: No present
Width of tubular esophagus: Not present

TUMOR:

LOCATION:

- Gastric region: Corpus, lesser curvature, posterior wall

- CONFIGURATION: Exophytic, non-circumferential

- DIMENSIONS: Diameters 5.5 x 2.7 cm
Depth of 1.7 cm

- DESCRIPTIVE CHARACTERISTICS: Villous type polyp with ulcerated surface. White tan cut surface with central well circumscribed nodule measuring 1.0 cm in diameter.

- PERFORATION: No

- DISTANCE FROM MARGINS:

- PROXIMAL 3.7 cm
- DISTAL 12.0 cm
- RADIAL 0.5 cm (non peritonealized soft tissue margin closest to deepest tumor penetration)

ESTIMATED DEPTH OF INVASION: Into submucosa.

LESIONS IN NONCANCEROUS STOMACH: 4 polyps ranging from 0.2 to 0.4 cm. These come to within 9.2 cm of the distal margin.

[page 3 of 4]
Surgical Pathology Consultation Report

ADDITIONAL STRUCTURES: There is a spleen adherent to the greater omentum, measuring 10.0 x 6.0 x 3.4 cm. The capsule shows some fibrous adhesions. Serial cuts are grossly unremarkable.

LYMPH NODES: Multiple perigastric lymph nodes along the greater and lesser curvatures are identified.

TUMOR BANKING: 2 pieces of tumor, 2 pieces of gastric mucosa

FROZEN SECTION: Proximal and distal margins submitted in blocks 1A-1B.

REPRESENTATIVE SECTIONS:

1A-1B frozen section proximal resubmitted
1C radial section proximal margin closest to tumor
1D proximal edge of tumor with adjacent mucosa
1E-1F full-thickness sections of tumor
1G distal edge of tumor with adjacent mucosa
1H-1I gastric mucosa with polyps
1J distal margin
1K spleen
1L-1N multiple lymph nodes per block, lesser omentum
1O 1 lymph node bisected, lesser omentum
1P representative slice, largest lymph node, lesser omentum
1Q-1T multiple lymph nodes per block, greater omentum
1U multiple lymph nodes, splenic hilum

2. The specimen container labeled with the patient's name and as "surgical waste", contains 1 piece of tissue in 10% buffered formalin. The tissue consists of a piece of fibrofatty tissue measuring 13.5 x 6.0 x 2.0 cm. A portion of ligament is identified within the specimen. No gross abnormalities are identified.

2A representative section of soft tissue

3. The specimen is labeled with the patient's name and as "gallbladder"

Resection specimen: Cholecystectomy

MEASUREMENTS:

Length 8.5 cm
Maximum diameter 2.7 cm

DESCRIPTION OF GALLBLADDER:

Serosa: Stained green, threadlike vascular pattern
Adventitial surface: size: 7.5 x 2.5 appearance: Unremarkable

Wall: Intact; 0.2 cm average thickness

Mucosa: Trabeculated

Contents: Green bile; no stones present.

Cystic duct:

- stenosis: No
- stone in lumen: No
- intraluminal tumor: No

Cystic duct lymph node: No

FOCAL LESIONS: No

TISSUE BANKING: No

[page 4 of 4]
Surgical Pathology Consultation Report

3A representative tissue

4. The specimen container is labeled with the patient's name and as "proximal stomach". The specimen consists of a wedge of mucosa measuring 1.2 x 0.7 cm. The specimen is bisected.
4A submitted in toto

5. The specimen container is labeled with the patient's name and as "distal and proximal rings". The specimen consists of two ring-shaped pieces of mucosa measuring 1.7 and 2.2 cm each in diameter. The larger piece is closed with blue suture material. Submitted in toto:

5A smaller piece

5B-5C larger piece

Quick Section Diagnosis

1. Proximal and distal margins negative for tumor.

Microscopic Description

Within the adenocarcinoma there is an area showing neuroendocrine differentiation (rosette formation and cytological features). This area shows focal positivity for synaptophysin and GFAP. This component is negative for neurofilament. The adenocarcinomatous focus is positive for: low molecular weight cytokeratin and pancytokeratin, CK19, focally positive for CK20. The mismatch repair proteins are retained and the tumour is negative for EBV.

HI/AA Discrepancy		✓
Review of Records	5/23/13	

Source: NCI Genomic Data Commons file 50935459-a892-4cbf-8b18-3ff3fac7e977 (TCGA-KB-A6F7.86DA3B37-396F-431F-9BE1-1D7F29828450.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).